CCDI case PBCCEB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/f40d4377-a128-4c22-b33b-5fcab23927ca

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.2 years (5,190 days).

Biospecimens (3 samples)
- Sample 0DO2ES: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DO2EZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DO2F8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
